Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OO, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OO-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

PROCEDURE: SPHS

Longstanding GE reflux disease, now presents with a distal esophageal adenocarcinoma. Operative Procedure/Tissue Submitted: Flexible E-scope, transhiatal esophagectomy - cervical esophagogastric anastomosis and J-tube placement.

1C8-0-3
adenocarcinoma, NOS 8140/3
Site: esophagus, distal third
C15.5

PROCEDURE: SPGD

1. "Liver biopsy." Received fresh for frozen section in a small container is a 1.1 x 0.5 x 0.3 cm, brown, irregular, soft tissue fragment. Frozen section control. (1 cassette)
2. "Fundic nodule." Received in formalin in a small container is a 1.4 x 1.0 x 0.7 cm, tan, partially encapsulated, soft tissue fragment. A possible resection margin is identified and inked blue. Sectioning reveals gray-yellow, solid and focally calcified cut surfaces. (1 cassette)
3. "Cervical esophageal margin." Received in formalin in a small container is a 1.8 cm in length x 3.3 cm in diameter, unoriented segment of esophagus. The specimen contains one opened end and one stapled end. Both the adventitial and mucosal surfaces are unremarkable. Bisected.
- 3A. Opened end submitted en face.
- 3B. Stapled end shaved and submitted en face. Staple line retained.
4. "Mid right periesophageal lymph node." Received in formalin in a small container are two anthracotic lymph nodes (0.7 and 0.9 cm), both of which are partially covered by adipose tissue. Both bisected and one inked blue. (1 cassette) Fat retained.
5. "Proximal stomach distal esophagus." Received in formalin in a small container is an esophagectomy specimen consisting of: Distal esophagus (7.1 cm in length), proximal stomach (5.6 cm in length) and attached periesophageal/perigastric adipose. There is a 4.1 x 3.6 cm flat, ulcerated mass located within the GE junction, 5.9 cm from the proximal margin and 4.0 cm from the distal margin. The mass occupies 80% of the lumen's circumference and invades through the adventitia, 0.2 cm away from the inked adipose margin. The esophageal and gastric walls surrounding the mass are focally indurated and thickened up to 1.4 cm. Found within the distal esophagus is a 1.5 x 1.2 cm ill-defined area of ulcerated mucosa, located 1.2 cm proximal to the mass and 3.4 cm from the nearest margin (proximal). Sectioning of this area reveals unremarkable cut surfaces. The remaining GE junction, esophageal and gastric mucosa are all unremarkable. Multiple possible lymph nodes are identified up to 2.1 cm in greatest dimension.
- 5A-D. Mass with greatest depth of invasion.

fw
10/9/12

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: M

- 5E. Cardia adjacent to mass (thickened wall).
5F. Esophagus adjacent to mass (thickened wall).
5G. Focal ulceration in mid esophagus.
5H. Seven possible lymph nodes submitted whole.
5I. Six possible lymph nodes submitted whole.
5J. Seven possible lymph nodes submitted whole.
5K. Seven possible lymph nodes submitted whole.
5L. Four possible lymph nodes submitted whole.
5M. Two possible lymph nodes both bisected and one inked blue. ()
5N. Two possible lymph nodes both bisected and one inked blue. ()
5O. Two possible lymph nodes both bisected and one inked blue. ()
5P. One possible lymph node serially sectioned.

FROZEN SECTION REPORT

1. Bile duct hamartoma.

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ESOPHAGUS CARCINOMA

LOCATION: Gastroesophageal junction

SIZE: 4.1 x 3.6 cm

TREATED PREOPERATIVELY: No

TYPE OF CARCINOMA: Adenocarcinoma, no Barrett's mucosa identified

DEPTH OF INVASION: Adventitia and perigastric adipose tissue

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 21/37

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T3 N3

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: M

PROCEDURE: SPDX

1. Liver, biopsy: Bile duct hamartoma. Negative for neoplasm.
2. Stomach, fundus, biopsy: Calcified gastrointestinal stromal tumor (1.4cm), low mitotic rate, histologically benign. Tumor extends to cauterized margin.
- 3 and 5. Distal esophagus and proximal stomach, resection: Invasive moderately differentiated adenocarcinoma (4.1 cm) extending into the paraesophageal soft tissue. Twenty-one of thirty-six lymph nodes positive for metastatic adenocarcinoma. Surgical margins negative. Please see template for details.
4. Lymph node, right mid paraesophageal, resection: One lymph node negative for neoplasm.

the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 5db27b79-275e-432e-8362-0f7b24e75c7e (TCGA-L5-A4OO.29F56353-10D0-4DBC-8E0E-598E685709D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).